Surgical pathology report (de-identified scan), TCGA case TCGA-58-8388, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8388-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, left, upper lobe: 21.5 x 16.5 x 4.5 cm

Tumor: 3.5 x 3.0 x 4.5 cm

Diagnosis:

Squamous Cell Carcinoma, mostly basaloid

pT2a, pN0 (0/35), pMx, G3

Supplementary examinations:

IHC:

Tumor positive for p63, CK5/6, some cells for CK14.

Tumor cells negative for: CD56, Chromogranin A, SPA, synaptophysin, TTF1.

Proliferation rate: 40 – 60%

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 32caae2e-63f3-4e6c-a572-5e17a6dadbba (TCGA-58-8388.E7A3F2B5-CC34-47E1-8A36-A552B3150847.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).